Gene-level copy-number profile of tumor specimen TCGA-62-8402-01A from TCGA case TCGA-62-8402, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.7 years (26,934 days).
Specimen TCGA-62-8402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.29b925ff-9035-4270-a880-9207b2acb56a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-62-8402-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/04bcd3be-3b5c-4d82-8031-ac70c6cb1987

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1; copy number 2: 1,919; copy number 3: 16,308; copy number 4: 9,975; copy number 5: 10,222; copy number 6: 14,267; copy number 7: 3,827; copy number 8: 166; copy number 10: 2,256; copy number 11: 711; copy number 16: 5; copy number 23: 5; copy number 44: 69; copy number 47: 40; copy number 69: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-62-8402-01A-11D-2322-01): tumor purity 0.5, ploidy 4.23, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,333,546–42,756,947, 9 genes (within-gene range 0–8): COX7A2L, AC025750.2, KCNG3, VDAC1P13, RPS13P3, MTA3, Metazoa_SRP, AC025750.1, AC074375.1.
- chr17:6,451,263–6,556,555, 2 genes (within-gene range 0–5): PITPNM3, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,695 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,712,740–42,712,847, 1 gene, copy number 8: RNU6-137P.
- chr5:58,198–50,970,187, 721 genes, copy number 11–23 (broad region; genes not listed).
- chr7:35,036,836–38,025,695, 58 genes, copy number 7: AC005400.1, DPY19L2P1, S100A11P2, TBX20, AC009531.1, AC007652.3, AC007652.2, AC007652.1, AC018647.3, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4, AC083864.5, AC083864.2, AC083864.4, AC083864.1, AC083864.3, MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1, AC007349.4, AC007349.1, AC007349.3, NPM1P18, AC007349.2, ELMO1, MIR1200, ELMO1-AS1, RPS17P13, RNU6-565P, RPS10P14, AC078843.1, Y_RNA, NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4.
- chr14:34,556,774–37,596,059, 77 genes, copy number 47–69 (within-gene range 5–69) (broad region; genes not listed).
- chr14:87,710,419–91,225,632, 69 genes, copy number 44 (within-gene range 4–44) (broad region; genes not listed).
- chr17:18,950,345–83,095,122, 2,311 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
